MMRF case MMRF_2595 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9baff632-2024-4025-b6fd-0c425fe93226

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.3 years (22,039 days); ISS stage: II; Days to last known disease status: 556 days (1.5 years); Days to last follow up: 556 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 75 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 92 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days; Days to treatment end: 344 days.
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 360 days; Days to treatment end: 451 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 498 days (1.4 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 501 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 505 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.634 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 44.7 mg/dL; Immunoglobulin G 56.3 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 294 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 30 g/L; Total Protein 9.5 g/dL; Glucose 7.15 mmol/L.
- Day 92 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.669 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 5.62 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 484 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Glucose 5.12 mmol/L.
- Day 211 (ECOG 1): Hemoglobin 7.07 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 6.6 mmol/L.
- Day 288 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.533 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.19 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 5.67 mmol/L.
- Day 380 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.824 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.85 mg/dL; Hemoglobin 5.89 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 8.3 g/dL; Glucose 4.79 mmol/L.
- Day 451 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.456 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 10.6 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 4.57 mmol/L.
- Day 556 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.336 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.193 mg/dL; Hemoglobin 5.15 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 9.35 mmol/L.

Other clinical attributes
- Day 1: Weight: 83 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2595_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2595_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
